Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A551, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A551-01A (Primary Tumor).

Gross Description: There is a skin flap of 7.5x5 cm in size with mushroom-like tumor with ulceration, up to 2cm in its diameter, 1.5 cm thick. On the cut section tumor is gray-yellow.

Microscopic Description: Amelanotic melanoma of the skin with superficial ulceration. Clark's level is V. Breslow thickness is 10 mm. Perifocal lymphoid infiltration. Six lymph nodes were examined. Two of them demonstrated metastases.

Diagnosis Details: Tumor Features: Ulcerated, Tumor Extent: Subcutaneous tissue invaded (Clark's level V), Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments: Original records read pT4bN1M0. According to the 7-th edition of TNM-classification this case should be staged as pT4bN2bM0.

Formatted Path Reports: SKIN TISSUE CHECKLIST

Specimen type: Excision of skin lesion

Tumor site: Skin, leg

Tumor size: 1.5 x 0 x 2 cm

Tumor features: Ulcerated, Pigmented

Satellite nodules: Not specified

Histologic type: Amelanotic melanoma

Histologic grade:

Lymph nodes: 2/6 positive for metastasis (Right inguinal lymph nodes 2/6)

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

1CD-0-3

Melanoma, amelanotic 8730/3

Site: skin, leg C44.7

fw
11/20/12

Reviewed In: [Signature]	Date Reviewed: 11/20/12	

Source: NCI Genomic Data Commons file 266c15c6-678b-43e6-be75-0f05eeb44efb (TCGA-EB-A551.29982C1C-609A-41B3-BB1E-47B568E3F035.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).